Somatic mutation profile of tumor specimen TCGA-97-8172-01A (aliquot TCGA-97-8172-01A-11D-2284-08) from TCGA case TCGA-97-8172, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 75.1 years (27,416 days).
Specimen TCGA-97-8172-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ae3ab4b5-d0a4-473d-8e34-d4ca663cd27a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-97-8172-10A (Blood Derived Normal), aliquot TCGA-97-8172-10A-01D-2284-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9f710d18-73e3-4576-8397-345d60eaa9e5

The open-access MAF lists 286 somatic variants for this specimen: 220 protein-altering or splice-affecting, 60 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 173, Silent 60, Nonsense Mutation 19, Frame Shift Del 15, Splice Site 8, RNA 5, Frame Shift Ins 4, Translation Start Site 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABAT | c.643G>A p.G215S | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs762050203, COSV99191071; called by muse, mutect2, varscan2
- ABCA13 | c.11005A>T p.S3669C | Missense Mutation (SNP) | VAF 36/157 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV71295045; called by muse, mutect2, varscan2
- ADGRV1 | c.628G>A p.G210S | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1334547636, COSV101316711; called by muse, mutect2, varscan2
- ADGRV1 | c.629G>A p.G210D | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1214561245, COSV101316712; called by muse, mutect2, varscan2
- AEBP1 | c.2335C>T p.P779S | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.18); catalogued as COSV99789205; called by muse, mutect2, varscan2
- AFF3 | c.454G>T p.G152W | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100420447; called by muse, mutect2, varscan2
- AK9 | c.5458G>A p.G1820R | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV101413996; called by muse, mutect2
- AKAP13 | c.3979G>T p.A1327S | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.272); catalogued as COSV100774926; called by muse, mutect2
- ANKRD26 | c.2261A>T p.K754I | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.772); catalogued as COSV101063509; called by muse, mutect2, varscan2
- APOB | c.12002C>A p.A4001E | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.057); catalogued as COSV99268792; called by muse, mutect2, varscan2
- ARHGAP27 | c.1144G>C p.G382R (on ENST00000428638 / NM_001282290.1; = p.G41R on NM_199282.3) | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as COSV100976675; called by muse, mutect2, varscan2
- ARHGAP35 | c.374T>C p.L125P | Missense Mutation (SNP) | VAF 9/99 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101351977; called by muse, mutect2
- ATP6V0D2 | c.580T>C p.Y194H | Missense Mutation (SNP) | VAF 36/197 reads (18%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.999); catalogued as COSV99572160; called by muse, mutect2, varscan2
- ATRNL1 | c.2365T>A p.S789T | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (0.79); PolyPhen benign (0.078); catalogued as COSV100747187; called by muse, mutect2, varscan2
- B4GALNT4 | c.1324G>T p.E442* | Nonsense Mutation (SNP) | VAF 9/36 reads (25%) | catalogued as COSV100327960; called by muse, mutect2, varscan2
- BCL11A | c.1539G>A p.M513I (on ENST00000335712 / NM_001365609.1; = p.M547I on NM_018014.4) | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.888); catalogued as COSV100186806; called by muse, mutect2, varscan2
- BCO1 | c.158G>T p.G53V | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371593751; called by muse, mutect2, varscan2
- BMP6 | c.1187G>T p.R396L | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.9); catalogued as COSV99307624; called by muse, mutect2, varscan2
- BRCA2 | c.3358G>T p.E1120* | Nonsense Mutation (SNP) | VAF 18/82 reads (22%) | catalogued as COSV101204743; called by muse, mutect2, varscan2
- BRIP1 | c.3649T>G p.W1217G | Missense Mutation (SNP) | VAF 4/65 reads (6%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.02); catalogued as COSV99371344; called by muse, mutect2
- BTBD1 | c.1022G>T p.R341L | Missense Mutation (SNP) | VAF 46/314 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV55602314, COSV99915799; called by muse, mutect2, varscan2
- C4A | c.3604C>A p.L1202M | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101418338, COSV71179346; called by muse, mutect2, varscan2
- CAPN13 | c.1769C>G p.S590W | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.911); catalogued as COSV99701317; called by muse, mutect2, varscan2
- CASS4 | c.818C>A p.P273H | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV100824565; called by muse, mutect2, varscan2
- CCDC198 | c.85G>T p.G29C | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT tolerated (0.39); PolyPhen benign (0.04); catalogued as COSV99371462; called by muse, mutect2, varscan2
- CCDC91 | c.740G>A p.C247Y | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.468); catalogued as COSV100082672; called by muse, mutect2, varscan2
- CDX1 | c.718C>A p.L240M | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.031); catalogued as COSV99199353; called by muse, mutect2
- CENPS | c.295A>C p.K99Q | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.876); catalogued as COSV100471922; called by muse, mutect2, varscan2
- CHD6 | c.2543C>T p.P848L | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.687); catalogued as COSV100498816; called by muse, mutect2, varscan2
- CHRM2 | c.360del p.D120Efs*10 | Frame Shift Del (DEL) | VAF 27/125 reads (22%) | catalogued as COSV57769100; called by mutect2, pindel, varscan2
- CLIC6 | c.2111A>C p.K704T (on ENST00000360731 / NM_001317009.2; = p.K686T on NM_053277.3) | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs1166479473, COSV100659361; called by muse, mutect2, varscan2
- CNTNAP4 | c.1747G>C p.A583P | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.878); catalogued as COSV100273820; called by muse, mutect2, varscan2
- COL14A1 | c.1907C>T p.T636M | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as rs771290485, COSV52850061; called by muse, mutect2, varscan2
- COLEC11 | c.425-1G>C p.X142_splice | Splice Site (SNP) | VAF 22/66 reads (33%) | catalogued as COSV99363820; called by muse, mutect2, varscan2
- CRACD | c.1421C>A p.A474D | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as COSV99950244; called by muse, mutect2
- CRB2 | c.2090C>G p.T697R | Missense Mutation (SNP) | VAF 38/154 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.425); catalogued as COSV100749516; called by muse, mutect2, varscan2
- DCANP1 | c.509C>A p.S170* | Nonsense Mutation (SNP) | VAF 8/77 reads (10%) | catalogued as COSV101538292; called by muse, mutect2, varscan2
- DHTKD1 | c.206A>T p.K69I | Missense Mutation (SNP) | VAF 33/141 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.356); catalogued as COSV99537047; called by muse, mutect2, varscan2
- DLGAP2 | c.1103G>T p.R368L | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV101423105, COSV70094440; called by muse, mutect2, varscan2
- DNAH5 | c.4726G>C p.D1576H | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.937); catalogued as COSV54218858, COSV99455818; called by muse, mutect2, varscan2
- DNAH8 | c.3630C>A p.N1210K | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as COSV100547540; called by muse, mutect2, varscan2
- DNAH9 | c.3055G>A p.E1019K | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.142); catalogued as COSV99309027; called by muse, mutect2, varscan2
- DNAH9 | c.4259T>C p.V1420A | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV99309029; called by muse, mutect2, varscan2
- DNAH9 | c.4764G>T p.K1588N | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99309034; called by muse, mutect2, varscan2
- DPP4 | c.709G>T p.E237* | Nonsense Mutation (SNP) | VAF 19/73 reads (26%) | catalogued as COSV100859173, COSV62110064; called by muse, mutect2, varscan2
- ENTHD1 | c.1123G>T p.D375Y | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.483); catalogued as COSV100289107; called by muse, mutect2, varscan2
- EPB41L2 | c.1463G>T p.C488F | Missense Mutation (SNP) | VAF 33/133 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100441584; called by muse, mutect2, varscan2
- EPB41L3 | c.2995G>T p.E999* | Nonsense Mutation (SNP) | VAF 33/131 reads (25%) | catalogued as COSV100550696; called by muse, mutect2, varscan2
- EPHA7 | c.789T>A p.C263* | Nonsense Mutation (SNP) | VAF 17/72 reads (24%) | catalogued as COSV100992564; called by muse, mutect2, varscan2
- EXTL3 | c.798G>A p.W266* | Nonsense Mutation (SNP) | VAF 17/79 reads (22%) | catalogued as COSV55038786; called by muse, mutect2, varscan2
- FAM135B | c.2294C>A p.T765N | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV52757001; called by muse, mutect2, varscan2
- FAM71B | c.758G>T p.S253I | Missense Mutation (SNP) | VAF 5/89 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.067); catalogued as COSV100262367; called by muse, mutect2
- FBXO30 | c.2109C>A p.H703Q | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99395499; called by muse, mutect2, varscan2
- FRMPD4 | c.3345T>A p.F1115L | Missense Mutation (SNP) | VAF 55/166 reads (33%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.001); catalogued as COSV101044409; called by muse, mutect2, varscan2
- FUT6 | c.1021T>A p.W341R | Missense Mutation (SNP) | VAF 23/107 reads (21%) | SIFT tolerated (0.84); PolyPhen benign (0.001); catalogued as COSV99745106; called by muse, mutect2, varscan2
- GABRA3 | c.767G>T p.R256L | Missense Mutation (SNP) | VAF 11/144 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.219); catalogued as COSV100943545, COSV64796500; called by muse, mutect2
- GCNT1 | c.1238G>T p.C413F | Missense Mutation (SNP) | VAF 25/123 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100946657, COSV100946690; called by muse, mutect2, varscan2
- GJD4 | c.271G>A p.V91I | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.153); catalogued as rs773198590, COSV58701977; called by muse, mutect2, varscan2
- GLP2R | c.1377C>G p.H459Q | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.37); catalogued as COSV99302657; called by muse, varscan2
- GPR61 | c.95C>T p.P32L | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.048); catalogued as rs949333514, COSV68177657; called by muse, mutect2, varscan2
- GRID2 | c.1477G>A p.D493N | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99948469; called by muse, mutect2, varscan2
- GXYLT1 | c.1200A>T p.K400N | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as COSV99789257; called by muse, mutect2, varscan2
- HAO2 | c.651G>T p.L217F | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100378336; called by muse, mutect2, varscan2
- HDAC9 | c.319G>T p.E107* | Nonsense Mutation (SNP) | VAF 3/15 reads (20%) | catalogued as COSV101288064; called by muse, mutect2
- HTR1A | c.928G>A p.E310K | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated (0.82); PolyPhen benign (0.089); catalogued as rs751102953, COSV60500791; called by muse, mutect2, varscan2
- HTR3C | c.79G>T p.A27S | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as rs768698957, COSV100570806, COSV59174161; called by muse, mutect2, varscan2
- IGSF22 | c.2423T>A p.L808Q (on ENST00000319338; = p.L909Q on NM_173588.4) | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV99773919; called by muse, mutect2, varscan2
- INTS12 | c.1A>C p.M1? | Translation Start Site (SNP) | VAF 38/153 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.813); catalogued as COSV100415968; called by muse, varscan2
- IQGAP2 | c.73G>A p.A25T | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV57175761; called by muse, mutect2, varscan2
- ITLN1 | c.208T>A p.C70S | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV100406444; called by muse, mutect2
- KCNH3 | c.276G>T p.E92D | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as COSV57791898; called by muse, mutect2
- KCNIP3 | c.746T>C p.M249T | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV99734726; called by muse, mutect2, varscan2
- KDM6A | c.461A>T p.Q154L | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.595); catalogued as COSV100938717; called by muse, mutect2, varscan2
- KHSRP | c.326A>G p.K109R | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs201259560, COSV100383189; called by muse, mutect2, varscan2
- KIF2B | c.625C>A p.P209T | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV99276469; called by muse, mutect2, varscan2
- KIF4B | c.55C>A p.L19M | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101469459, COSV70531634; called by muse, mutect2, varscan2
- KPRP | c.363G>T p.Q121H | Missense Mutation (SNP) | VAF 32/288 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.017); catalogued as COSV100908845; called by muse, mutect2, varscan2
- LCA5 | c.893A>T p.Y298F | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs934682734, COSV100878402; called by muse, mutect2
- LIN28B | c.105G>T p.K35N | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100559165; called by muse, mutect2, varscan2
- LRP1 | c.12037G>T p.G4013W | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99677903; called by muse, mutect2, varscan2
- LSR | c.1738A>T p.R580W (on ENST00000361790; = p.R561W on NM_015925.6) | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); catalogued as rs747898152, COSV99723554; called by muse, mutect2, varscan2
- LZTS1 | c.976C>G p.R326G | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV99743022, COSV99743459; called by muse, mutect2, varscan2
- MAGEB10 | c.998del p.G333Vfs*18 | Frame Shift Del (DEL) | VAF 3/26 reads (12%) | catalogued as COSV63310687; called by mutect2, pindel
- MAP2K6 | c.721T>A p.W241R | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV100765162; called by muse, mutect2
- MARCKS | c.916G>T p.A306S | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.027); catalogued as rs1286719810, COSV100893102; called by muse, mutect2, varscan2
- MCF2L | c.322G>T p.D108Y (on ENST00000375608; = p.D76Y on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV100983181; called by muse, mutect2, varscan2
- MDGA2 | c.2024A>G p.Y675C (on ENST00000399232 / NM_001113498.2; = p.Y377C on NM_182830.4) | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.769); catalogued as rs779642688, COSV62119225, COSV62119393; called by muse, mutect2, varscan2
- MEF2D | c.1540C>T p.R514W | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762225408, COSV61728224; called by muse, mutect2, varscan2
- MEGF8 | c.8114C>T p.P2705L (on ENST00000251268 / NM_001271938.2; = p.P2638L on NM_001410.3) | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.236); catalogued as COSV99239917; called by muse, varscan2
- METAP1D | c.761T>C p.I254T | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV100250203; called by muse, mutect2, varscan2
- MFSD6L | c.190C>T p.P64S | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1408522203, COSV100266566; called by muse, mutect2, varscan2
- MORC4 | c.886G>T p.A296S | Missense Mutation (SNP) | VAF 36/145 reads (25%) | SIFT tolerated (0.7); PolyPhen benign (0.133); catalogued as COSV99717793; called by muse, mutect2, varscan2
- MRE11 | c.1969C>A p.P657T (on ENST00000323929 / NM_005591.4; = p.P629T on NM_005590.4) | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.001); catalogued as COSV100120201, COSV60575208; called by muse, mutect2, varscan2
- MSLNL | c.1025C>A p.T342N | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.163); catalogued as COSV99558938; called by muse, mutect2, varscan2
- MUC16 | c.899T>A p.I300K | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.096); catalogued as COSV101202315; called by muse, mutect2, varscan2
- MYH1 | c.1889C>A p.A630E | Missense Mutation (SNP) | VAF 18/124 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.023); catalogued as COSV99877268; called by muse, mutect2, varscan2
- MYH14 | c.2336G>T p.R779L | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV51833882; called by muse, mutect2, varscan2
- MYH8 | c.2201C>G p.P734R | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101239020; called by muse, mutect2, varscan2
- MYO3A | c.3904G>T p.E1302* | Nonsense Mutation (SNP) | VAF 12/82 reads (15%) | catalogued as COSV56349678, COSV99780593; called by muse, mutect2, varscan2
- NAV2 | c.6407C>T p.P2136L (on ENST00000396087 / NM_001244963.2; = p.P2077L on NM_145117.5) | Missense Mutation (SNP) | VAF 30/93 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100217817; called by muse, mutect2, varscan2
- NDST4 | c.38C>T p.T13I | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.043); catalogued as rs1363286124, COSV99997841, COSV99998415; called by muse, mutect2
- NEFH | c.938C>A p.S313* | Nonsense Mutation (SNP) | VAF 27/161 reads (17%) | catalogued as COSV100151936; called by muse, mutect2, varscan2
- NEK10 | c.1430A>C p.D477A | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); catalogued as COSV100412438; called by muse, mutect2, varscan2
- NFIA | c.1131G>T p.Q377H | Missense Mutation (SNP) | VAF 28/104 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV100783408, COSV63610040; called by muse, mutect2, varscan2
- NLGN4X | c.184T>A p.L62I | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.937); catalogued as COSV99324679; called by muse, mutect2, varscan2
- NOBOX | c.563C>A p.P188Q | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.031); catalogued as COSV99779856; called by muse, mutect2, varscan2
- NOTCH4 | c.4466G>A p.R1489Q | Missense Mutation (SNP) | VAF 26/141 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs753820483, COSV66678543, COSV66685378; called by muse, mutect2, varscan2
- NOTCH4 | c.2559C>A p.C853* | Nonsense Mutation (SNP) | VAF 17/103 reads (17%) | catalogued as COSV100901268; called by muse, mutect2, varscan2
- NPAP1 | c.2813G>T p.G938V | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.685); catalogued as COSV61512806; called by muse, mutect2, varscan2
- NRAP | c.2423T>A p.L808Q (on ENST00000359988 / NM_001322945.2; = p.L773Q on NM_006175.4) | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.284); catalogued as COSV100748690, COSV63494193; called by muse, mutect2, varscan2
- NUP98 | c.857G>T p.S286I | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.059); catalogued as COSV100263764; called by muse, varscan2
- OR10G8 | c.160C>T p.H54Y | Missense Mutation (SNP) | VAF 35/172 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); catalogued as COSV101461904; called by muse, mutect2, varscan2
- OR10J1 | c.368A>T p.Y123F | Missense Mutation (SNP) | VAF 35/162 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.656); catalogued as COSV101420082, COSV71128661; called by muse, mutect2, varscan2
- OR10J3 | c.160C>A p.H54N | Missense Mutation (SNP) | VAF 26/180 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.184); catalogued as COSV59955751; called by muse, mutect2, varscan2
- OR2D3 | c.220C>A p.P74T | Missense Mutation (SNP) | VAF 24/128 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100505186; called by muse, mutect2, varscan2
- OR2G3 | c.831C>A p.F277L | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.211); catalogued as COSV100180848; called by muse, mutect2, varscan2
- OR2W3 | c.136A>T p.I46F | Missense Mutation (SNP) | VAF 45/128 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV100831901; called by muse, mutect2, varscan2
- OR4A15 | c.796G>T p.D266Y | Missense Mutation (SNP) | VAF 35/249 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100124427; called by muse, mutect2, varscan2
- OR51G2 | c.582T>A p.C194* | Nonsense Mutation (SNP) | VAF 11/56 reads (20%) | catalogued as COSV100432275; called by muse, mutect2, varscan2
- OR52D1 | c.461G>A p.R154H | Missense Mutation (SNP) | VAF 56/220 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs760829167, COSV59487388; called by muse, mutect2, varscan2
- OR52E6 | c.468C>G p.Y156* | Nonsense Mutation (SNP) | VAF 31/151 reads (21%) | catalogued as COSV100259615, COSV61433851; called by muse, mutect2, varscan2
- OR5AS1 | c.882C>A p.N294K | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100546439; called by muse, mutect2, varscan2
- OSGEP | c.508-2A>G p.X170_splice | Splice Site (SNP) | VAF 30/144 reads (21%) | catalogued as rs746997649, COSV99248332; called by muse, mutect2, varscan2
- PAMR1 | c.1334-1G>A p.X445_splice (on ENST00000619888 / NM_001001991.3; = p.X462_splice on NM_015430.4) | Splice Site (SNP) | VAF 10/61 reads (16%) | catalogued as COSV99553505; called by muse, mutect2, varscan2
- PCDH11X | c.1015G>T p.A339S | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs776954555, COSV100016411; called by muse, mutect2, varscan2
- PCDH15 | c.569T>C p.V190A | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT tolerated (0.31); PolyPhen benign (0.009); catalogued as COSV100229867; called by muse, mutect2, varscan2
- PCLO | c.5658G>T p.L1886F | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV100439659; called by muse, mutect2, varscan2
- PCNX2 | c.4698G>T p.W1566C | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.971); catalogued as COSV99270127; called by muse, mutect2, varscan2
- PDE10A | c.1227C>A p.N409K | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.996); catalogued as COSV100606224; called by muse, mutect2, varscan2
- PDZRN4 | c.793G>A p.G265R | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101284521; called by muse, mutect2, varscan2
- PHLPP2 | c.2152G>A p.V718I | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.978); catalogued as rs1417809712, COSV100673885; called by muse, mutect2, varscan2
- PIGC | c.77A>G p.D26G | Missense Mutation (SNP) | VAF 37/138 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.19); catalogued as rs756248499, COSV99278474; called by muse, mutect2, varscan2
- PLAGL2 | c.787A>T p.S263C | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.765); catalogued as COSV99867694; called by muse, mutect2, varscan2
- PLOD2 | c.218A>G p.E73G | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.424); catalogued as COSV99283485; called by muse, mutect2, varscan2
- PLXNC1 | c.2218G>A p.G740R | Missense Mutation (SNP) | VAF 40/174 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.11); catalogued as COSV99314161; called by muse, mutect2, varscan2
- PPP1R36 | c.353T>A p.L118Q | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100073105; called by muse, mutect2, varscan2
- PTGDR | c.295G>A p.A99T | Missense Mutation (SNP) | VAF 15/121 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.046); catalogued as COSV100035809; called by muse, mutect2, varscan2
- PTPRD | c.3542G>A p.R1181H | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs781067774, COSV61928613, COSV61938527, COSV61976608; called by muse, mutect2
- RB1 | c.1893A>T p.Q631H | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.481); catalogued as COSV99927412; called by muse, mutect2, varscan2
- REG3A | c.426C>A p.S142R | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.027); catalogued as rs758760547, COSV100532985, COSV59410796; called by muse, mutect2, varscan2
- RFLNA | c.487C>G p.R163G (on ENST00000546355 / NM_001365156.1; = p.R82G on NM_181709.4) | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.092); catalogued as COSV100133469; called by muse, mutect2, varscan2
- RHOB | c.406C>T p.Q136* | Nonsense Mutation (SNP) | VAF 13/106 reads (12%) | catalogued as COSV99695395; called by muse, mutect2, varscan2
- RICTOR | c.155C>A p.S52* | Nonsense Mutation (SNP) | VAF 28/116 reads (24%) | catalogued as COSV99705939; called by muse, mutect2, varscan2
- ROBO2 | c.1264C>T p.Q422* | Nonsense Mutation (SNP) | VAF 18/68 reads (26%) | catalogued as COSV100170794; called by muse, mutect2, varscan2
- RYR1 | c.3932C>A p.P1311H | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.403); catalogued as COSV100617385; called by muse, mutect2, varscan2
- RYR2 | c.12790C>A p.L4264M | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.202); catalogued as COSV100773428; called by muse, mutect2, varscan2
- SBF1 | c.1543T>C p.W515R | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.804); catalogued as COSV100818157; called by muse, mutect2, varscan2
- SCAF1 | c.428C>A p.P143H | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.742); catalogued as COSV100862354; called by muse, mutect2, varscan2
- SEMA3A | c.1232A>G p.N411S | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.317); catalogued as COSV99548346; called by muse, mutect2, varscan2
- SERBP1 | c.521G>A p.G174D | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV100769192; called by muse, mutect2, varscan2
- SETX | c.6801C>G p.F2267L | Missense Mutation (SNP) | VAF 22/115 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99811328; called by muse, mutect2, varscan2
- SF3B4 | c.607C>T p.Q203* | Nonsense Mutation (SNP) | VAF 41/96 reads (43%) | catalogued as COSV99641521; called by muse, mutect2, varscan2
- SHD | c.971A>T p.Q324L | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.048); catalogued as COSV100010569; called by muse, mutect2, varscan2
- SIAH2 | c.641G>T p.G214V | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); catalogued as COSV100469510; called by muse, mutect2, varscan2
- SLC13A3 | c.1187G>T p.R396M | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.859); catalogued as COSV99287512; called by muse, mutect2, varscan2
- SLC25A38 | c.517G>T p.G173W | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99827975; called by muse, mutect2, varscan2
- SLCO1C1 | c.1714G>A p.G572R | Missense Mutation (SNP) | VAF 38/128 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV99860256; called by muse, varscan2
- SLCO5A1 | c.2202T>G p.F734L | Missense Mutation (SNP) | VAF 28/182 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.083); catalogued as rs761664902, COSV52659069, COSV99481416; called by muse, mutect2, varscan2
- SORL1 | c.3335G>C p.C1112S | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.521); catalogued as COSV99495916; called by muse, mutect2, varscan2
- SPEG | c.8592T>A p.S2864R | Missense Mutation (SNP) | VAF 13/117 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.224); catalogued as COSV100405967; called by muse, mutect2, varscan2
- SPTA1 | c.5911-1G>T p.X1971_splice | Splice Site (SNP) | VAF 110/280 reads (39%) | catalogued as COSV100935845; called by muse, mutect2, varscan2
- SRGAP1 | c.1034T>C p.V345A | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.15); catalogued as COSV100755252; called by muse, mutect2
- ST6GAL2 | c.160G>T p.V54L | Missense Mutation (SNP) | VAF 11/36 reads (31%) | PolyPhen benign (0); catalogued as COSV100868343; called by muse, mutect2, varscan2
- STAB1 | c.1996T>A p.C666S | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100402471; called by muse, mutect2
- STAU2 | c.411-2A>T p.X137_splice (on ENST00000524300 / NM_001164380.2; = p.X105_splice on NM_014393.2) | Splice Site (SNP) | VAF 15/82 reads (18%) | catalogued as COSV100869355; called by muse, mutect2, varscan2
- STON2 | c.2479G>T p.G827C (on ENST00000649389 / NM_001366849.2; = p.G770C on NM_001256430.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99965330; called by muse, mutect2, varscan2
- SVEP1 | c.9736A>G p.S3246G | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated (0.36); PolyPhen benign (0.136); catalogued as rs1564131407, COSV99930125; called by muse, mutect2
- SYT10 | c.263C>T p.P88L | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs773702624, COSV99952153; called by muse, mutect2, varscan2
- TELO2 | c.1216G>T p.G406C | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99248846; called by muse, mutect2, varscan2
- TEX13A | c.283G>T p.G95C | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as COSV100782256; called by muse, mutect2, varscan2
- TEX15 | c.156A>T p.R52S (on ENST00000256246; = p.R435S on NM_001350162.2) | Missense Mutation (SNP) | VAF 20/148 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99822418; called by muse, mutect2, varscan2
- TEX15 | c.155G>T p.R52I (on ENST00000256246; = p.R435I on NM_001350162.2) | Missense Mutation (SNP) | VAF 20/150 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56341466, COSV99822419; called by muse, mutect2, varscan2
- TGIF2LX | c.193C>A p.L65I | Missense Mutation (SNP) | VAF 50/103 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV99383611; called by muse, mutect2, varscan2
- TH | c.539G>T p.R180L (on ENST00000381178 / NM_199292.3; = p.R149L on NM_000360.4) | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.274); catalogued as rs1357867110, COSV100147215; called by muse, mutect2, varscan2
- TM9SF4 | c.556A>T p.I186F | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT tolerated (0.4); PolyPhen benign (0.035); catalogued as COSV99455367; called by muse, mutect2, varscan2
- TMEM200A | c.1346C>T p.A449V | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV51653530, COSV51654749; called by muse, mutect2
- TMPRSS11A | c.489T>A p.N163K | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT tolerated (0.55); PolyPhen benign (0.22); catalogued as COSV100602874; called by muse, mutect2, varscan2
- TRAF7 | c.1112G>T p.R371L | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.415); catalogued as COSV100399903, COSV104397263, COSV58215487; called by muse, mutect2, varscan2
- TRIM36 | c.1681G>A p.D561N | Missense Mutation (SNP) | VAF 11/111 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.111); catalogued as COSV99142957; called by muse, mutect2, varscan2
- TRPM1 | c.4273C>T p.P1425S | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.013); catalogued as COSV99857010; called by muse, mutect2, varscan2
- TRPM6 | c.1223C>T p.A408V | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.189); catalogued as rs1272661781, COSV100667169; called by muse, mutect2, varscan2
- TSGA13 | c.271G>T p.D91Y | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100746817, COSV100746848; called by muse, mutect2, varscan2
- TTK | c.139+1G>T p.X47_splice | Splice Site (SNP) | VAF 14/88 reads (16%) | catalogued as COSV100036724; called by muse, mutect2, varscan2
- TUBB8 | c.469G>T p.E157* | Nonsense Mutation (SNP) | VAF 15/120 reads (13%) | catalogued as COSV100226237; called by muse, mutect2, varscan2
- TXLNB | c.694G>T p.A232S | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as COSV100625229; called by muse, mutect2, varscan2
- UBTD1 | c.166G>T p.D56Y | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100081112; called by muse, mutect2, varscan2
- UGT2A2 | c.377C>A p.T126N | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV99685095; called by muse, mutect2, varscan2
- UGT2B28 | c.846C>G p.C282W | Missense Mutation (SNP) | VAF 54/239 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100159124; called by muse, mutect2, varscan2
- UTP20 | c.3417+1G>A p.X1139_splice | Splice Site (SNP) | VAF 16/60 reads (27%) | catalogued as COSV99882820; called by muse, mutect2, varscan2
- VANGL2 | c.430G>T p.A144S | Missense Mutation (SNP) | VAF 7/99 reads (7%) | SIFT tolerated (0.5); PolyPhen benign (0.093); catalogued as rs1426300628, COSV100925628; called by muse, mutect2
- VCAN | c.8656A>G p.I2886V | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs746325639, COSV99427875; called by muse, mutect2, varscan2
- VCAN | c.9940C>A p.R3314S | Missense Mutation (SNP) | VAF 25/118 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54113152, COSV99427878; called by muse, mutect2, varscan2
- VPS28 | c.402+1G>C p.X134_splice | Splice Site (SNP) | VAF 20/69 reads (29%) | catalogued as COSV99466040; called by muse, mutect2, varscan2
- WIPF1 | c.1064G>A p.G355D | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99769671; called by muse, mutect2, varscan2
- WNT7A | c.536T>A p.L179H | Missense Mutation (SNP) | VAF 45/178 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99541893; called by muse, mutect2, varscan2
- XIRP2 | c.3034C>A p.P1012T (on ENST00000628543; = p.P1187T on NM_152381.6) | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV99749261; called by muse, mutect2, varscan2
- ZBTB20 | c.1146del p.I383* (on ENST00000474710 / NM_001164342.2; = p.I310* on NM_015642.6 and 4 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 10/46 reads (22%) | catalogued as COSV61848520; called by mutect2, pindel, varscan2
- ZEB2 | c.936C>G p.C312W | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as CM147439, COSV100357288; called by muse, varscan2
- ZNF124 | c.922C>T p.H308Y (on ENST00000543802 / NM_001297568.1; = p.H246Y on NM_003431.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100517950; called by muse, mutect2, varscan2
- ZNF440 | c.800G>T p.S267I | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.978); catalogued as COSV100407801; called by muse, mutect2, varscan2
- ASH2L | c.1774del p.R592Afs*3 | Frame Shift Del (DEL) | VAF 16/128 reads (13%) | called by mutect2, pindel, varscan2
- CACNG2 | c.627_631del p.A210Gfs*83 | Frame Shift Del (DEL) | VAF 29/155 reads (19%) | called by mutect2, pindel, varscan2
- CFAP20DC | c.2171del p.P724Hfs*14 (on ENST00000482387 / NM_001351530.2; = p.P473Hfs*14 on NM_198463.4 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 6/34 reads (18%) | called by mutect2, pindel, varscan2
- COL19A1 | c.1673del p.G558Efs*10 | Frame Shift Del (DEL) | VAF 13/67 reads (19%) | called by mutect2, pindel, varscan2
- CT45A9 | c.82C>A p.Q28K | Missense Mutation (SNP) | VAF 16/214 reads (7%) | SIFT tolerated (1); PolyPhen probably damaging (0.986); called by muse, mutect2
- EFCAB5 | c.3985del p.R1329Efs*30 | Frame Shift Del (DEL) | VAF 7/63 reads (11%) | called by mutect2, pindel, varscan2
- EHF | c.405_406dup p.E136Vfs*6 | Frame Shift Ins (INS) | VAF 17/132 reads (13%) | called by mutect2, pindel, varscan2
- ERO1A | c.1092dup p.A365Cfs*4 | Frame Shift Ins (INS) | VAF 9/80 reads (11%) | called by mutect2, pindel
- FPGS | c.1513del p.H505Tfs*62 | Frame Shift Del (DEL) | VAF 14/62 reads (23%) | called by mutect2, pindel, varscan2
- INSYN1 | c.655_656del p.P219* | Frame Shift Del (DEL) | VAF 10/38 reads (26%) | called by mutect2, pindel, varscan2
- ITPR2 | c.5487dup p.I1830Hfs*5 | Frame Shift Ins (INS) | VAF 24/102 reads (24%) | called by mutect2, pindel, varscan2
- KRTAP12-3 | c.171del p.V58* | Frame Shift Del (DEL) | VAF 12/112 reads (11%) | called by pindel, varscan2
- LRRC7 | c.2951dup p.S985Vfs*6 (on ENST00000651989 / NM_001370785.2; = p.S952Vfs*6 on NM_001330635.3 and 2 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 13/60 reads (22%) | called by mutect2, pindel, varscan2
- NCOA4 | c.118C>T p.Q40* | Nonsense Mutation (SNP) | VAF 14/140 reads (10%) | called by muse, mutect2
- NUP98 | c.824del p.G275Afs*34 | Frame Shift Del (DEL) | VAF 17/91 reads (19%) | called by pindel, varscan2
- POTEA | c.178C>A p.H60N | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- SLCO5A1 | c.662_663del p.P221Lfs*38 | Frame Shift Del (DEL) | VAF 15/73 reads (21%) | called by mutect2, pindel, varscan2
- TRBV3-1 | c.139G>T p.G47C | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- TRIM72 | c.511del p.A171Pfs*42 | Frame Shift Del (DEL) | VAF 20/71 reads (28%) | called by mutect2, pindel, varscan2
- ZNF18 | c.526del p.E176Sfs*3 | Frame Shift Del (DEL) | VAF 53/241 reads (22%) | called by mutect2, pindel, varscan2
- ADGRF3 | c.1533G>T p.L511= (on ENST00000311519 / NM_001145168.1; = p.L312= on NM_153835.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/49 reads (20%) | catalogued as COSV100275566; called by muse, mutect2, varscan2
- AGBL1 | c.1572G>T p.V524= | Silent (SNP) | VAF 21/88 reads (24%) | catalogued as COSV66857965, COSV66879497; called by muse, mutect2, varscan2
- ANKS1B | c.528G>T p.V176= | Silent (SNP) | VAF 10/48 reads (21%) | catalogued as COSV100249028, COSV61348979; called by muse, mutect2, varscan2
- ARF5 | c.300C>T p.V100= | Silent (SNP) | VAF 23/88 reads (26%) | catalogued as COSV99134007; called by muse, mutect2, varscan2
- ASPM | c.7092C>T p.I2364= | Silent (SNP) | VAF 16/194 reads (8%) | catalogued as COSV99661367; called by muse, mutect2
- CACNA1I | c.594G>T p.L198= | Silent (SNP) | VAF 27/145 reads (19%) | catalogued as COSV100361940; called by muse, mutect2, varscan2
- CLSTN3 | c.813G>A p.E271= | Silent (SNP) | VAF 9/46 reads (20%) | catalogued as COSV99867876; called by muse, mutect2, varscan2
- COLGALT2 | c.1788G>A p.R596= | Silent (SNP) | VAF 21/67 reads (31%) | catalogued as COSV100730947; called by muse, mutect2, varscan2
- CPXM1 | c.193C>A p.R65= | Silent (SNP) | VAF 21/99 reads (21%) | catalogued as COSV101013866, COSV66046417; called by muse, mutect2, varscan2
- CRACD | c.1422C>A p.A474= | Silent (SNP) | VAF 3/17 reads (18%) | catalogued as COSV99950247, COSV99950307; called by muse, mutect2
- DDX24 | c.1323G>T p.V441= | Silent (SNP) | VAF 20/121 reads (17%) | catalogued as COSV100428178; called by muse, mutect2, varscan2
- DEPDC1 | c.2238A>G p.L746= (on ENST00000456315 / NM_001114120.3; = p.L462= on NM_017779.6) | Silent (SNP) | VAF 20/144 reads (14%) | catalogued as rs1385468208, COSV100920535; called by muse, mutect2, varscan2
- FAT3 | c.12735C>A p.S4245= | Silent (SNP) | VAF 21/131 reads (16%) | catalogued as COSV99972703; called by muse, mutect2, varscan2
- FCRL5 | c.543C>A p.V181= | Silent (SNP) | VAF 17/158 reads (11%) | catalogued as COSV100709449; called by muse, mutect2, varscan2
- FRAS1 | c.2016G>T p.G672= | Silent (SNP) | VAF 12/76 reads (16%) | catalogued as COSV99356857; called by muse, mutect2
- GLI2 | c.3147G>T p.V1049= (on ENST00000361492 / NM_001374353.1; = p.V1066= on NM_005270.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 11/65 reads (17%) | catalogued as COSV100084670; called by muse, mutect2, varscan2
- GRM3 | c.447T>C p.S149= | Silent (SNP) | VAF 22/94 reads (23%) | catalogued as COSV64476445; called by muse, mutect2, varscan2
- GTPBP3 | c.1128G>T p.S376= | Silent (SNP) | VAF 3/31 reads (10%) | catalogued as COSV100259230; called by muse, mutect2
- HDAC9 | c.318G>T p.L106= | Silent (SNP) | VAF 3/15 reads (20%) | catalogued as COSV101288060; called by muse, mutect2
- HOXA3 | c.1098C>T p.F366= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as COSV57828688; called by muse, mutect2, varscan2
- HTRA3 | c.1104G>A p.L368= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as rs761139127, COSV100246614, COSV56471740; called by muse, mutect2, varscan2
- IGLV3-21 | c.195C>A p.V65= | Silent (SNP) | VAF 4/21 reads (19%) | catalogued as rs780020336; called by mutect2, varscan2
- INO80 | c.4212A>T p.T1404= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as COSV100732108; called by muse, mutect2, varscan2
- KIAA0408 | c.1644T>C p.S548= | Silent (SNP) | VAF 11/57 reads (19%) | catalogued as COSV100847126; called by muse, mutect2, varscan2
- KRT3 | c.525C>A p.I175= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as rs1339960465, COSV100527390, COSV58816188; called by muse, mutect2
- KRTAP10-11 | c.636C>T p.S212= | Silent (SNP) | VAF 11/227 reads (5%) | catalogued as rs900191381, COSV100556109; called by muse, mutect2
- LRIT1 | c.153C>A p.T51= | Silent (SNP) | VAF 7/35 reads (20%) | catalogued as COSV100928199, COSV64512475; called by muse, mutect2, varscan2
- LRRK1 | c.1665G>T p.L555= | Silent (SNP) | VAF 18/69 reads (26%) | catalogued as COSV99443968; called by muse, mutect2, varscan2
- MAN2B1 | c.2169C>T p.D723= | Silent (SNP) | VAF 23/127 reads (18%) | catalogued as COSV99667478; called by muse, mutect2, varscan2
- MIGA2 | c.6G>T p.A2= | Silent (SNP) | VAF 3/16 reads (19%) | catalogued as COSV52976454, COSV99477975; called by muse, mutect2
- MLC1 | c.207G>T p.S69= | Silent (SNP) | VAF 11/61 reads (18%) | catalogued as COSV100286648; called by muse, mutect2, varscan2
- MPL | c.1242G>A p.S414= | Silent (SNP) | VAF 11/71 reads (15%) | catalogued as rs544064034, COSV65244840; called by muse, mutect2, varscan2
- MSLNL | c.1026C>A p.T342= | Silent (SNP) | VAF 19/62 reads (31%) | catalogued as COSV99558935; called by muse, mutect2, varscan2
- MUC16 | c.41034C>A p.T13678= | Silent (SNP) | VAF 9/55 reads (16%) | catalogued as COSV101110134; called by muse, mutect2, varscan2
- NLRC4 | c.2436C>T p.V812= | Silent (SNP) | VAF 16/83 reads (19%) | catalogued as rs766493286, COSV100707546; called by muse, mutect2, varscan2
- OR13C3 | c.180C>A p.L60= | Silent (SNP) | VAF 25/97 reads (26%) | catalogued as COSV101053371; called by muse, mutect2, varscan2
- OR2W3 | c.135C>A p.I45= | Silent (SNP) | VAF 45/127 reads (35%) | catalogued as COSV100831899, COSV64456126, COSV64456854; called by muse, mutect2, varscan2
- PCK1 | c.723C>A p.L241= | Silent (SNP) | VAF 18/167 reads (11%) | catalogued as COSV60126572; called by muse, mutect2, varscan2
- PGA5 | c.798C>T p.I266= | Silent (SNP) | VAF 18/180 reads (10%) | catalogued as rs373857767; called by muse, mutect2, varscan2
- PHACTR4 | c.1377G>T p.L459= (on ENST00000373839 / NM_001350159.2; = p.L469= on NM_023923.4) | Silent (SNP) | VAF 31/110 reads (28%) | catalogued as COSV100868516; called by muse, mutect2, varscan2
- PPFIBP1 | c.2475G>T p.A825= (on ENST00000318304 / NM_177444.3; = p.A819= on NM_003622.4) | Silent (SNP) | VAF 38/220 reads (17%) | catalogued as rs746681298, COSV57290047, COSV99945708; called by muse, mutect2, varscan2
- PPP1R32 | c.798C>A p.A266= | Silent (SNP) | VAF 5/35 reads (14%) | catalogued as COSV100088032; called by muse, mutect2, varscan2
- PZP | c.1956T>C p.Y652= | Silent (SNP) | VAF 16/58 reads (28%) | catalogued as COSV99740155; called by muse, mutect2, varscan2
- RPL9 | c.381G>T p.R127= | Silent (SNP) | VAF 18/55 reads (33%) | catalogued as COSV99787942; called by muse, mutect2, varscan2
- RTL4 | c.60A>G p.A20= | Silent (SNP) | VAF 53/110 reads (48%) | catalogued as COSV100466209; called by muse, mutect2, varscan2
- SLC24A3 | c.684C>T p.I228= | Silent (SNP) | VAF 14/57 reads (25%) | catalogued as rs1189822241, COSV60129891; called by muse, mutect2, varscan2
- SLC35C2 | c.189C>T p.S63= | Silent (SNP) | VAF 18/59 reads (31%) | catalogued as rs1252847136, COSV99709682; called by muse, mutect2, varscan2
- SPATA31A1 | c.1143C>T p.P381= | Silent (SNP) | VAF 37/239 reads (15%) | called by muse, mutect2, varscan2
- SPEM1 | c.153C>T p.S51= | Silent (SNP) | VAF 9/51 reads (18%) | catalogued as rs1404254418, COSV100081350; called by muse, mutect2, varscan2
- TCTN2 | c.348C>A p.S116= | Silent (SNP) | VAF 23/125 reads (18%) | catalogued as COSV100315495; called by muse, mutect2, varscan2
- TGIF2LX | c.192C>A p.I64= | Silent (SNP) | VAF 50/102 reads (49%) | catalogued as rs756771231, COSV52213255, COSV52213926, COSV99383609; called by muse, mutect2, varscan2
- TNS4 | c.1759C>T p.L587= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as COSV99564255; called by muse, mutect2, varscan2
- TYR | c.1461C>A p.V487= | Silent (SNP) | VAF 15/71 reads (21%) | catalogued as rs766773844, COSV99635724; called by muse, mutect2, varscan2
- UBE2G2 | c.474C>T p.I158= | Silent (SNP) | VAF 10/113 reads (9%) | catalogued as rs373891294; called by muse, mutect2
- UGGT1 | c.264A>T p.S88= | Silent (SNP) | VAF 25/70 reads (36%) | catalogued as COSV99391343; called by muse, mutect2, varscan2
- WNT10A | c.687G>T p.L229= | Silent (SNP) | VAF 12/41 reads (29%) | catalogued as COSV99297661; called by muse, mutect2, varscan2
- XIRP2 | c.8955G>C p.S2985= (on ENST00000628543; = p.S3160= on NM_152381.6) | Silent (SNP) | VAF 18/107 reads (17%) | catalogued as COSV99746534, COSV99749265; called by muse, mutect2, varscan2
- ZBTB20 | c.798G>T p.V266= (on ENST00000474710 / NM_001164342.2; = p.V193= on NM_015642.6 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 11/41 reads (27%) | catalogued as rs1176030864, COSV100613381, COSV100615553; called by muse, mutect2, varscan2
- ZNF101 | c.228G>T p.G76= | Silent (SNP) | VAF 13/71 reads (18%) | catalogued as COSV100543661; called by muse, mutect2, varscan2
- ZNF521 | c.1059C>A p.S353= | Silent (SNP) | VAF 20/59 reads (34%) | catalogued as rs375746812, COSV64128255; called by muse, mutect2, varscan2
- EIF5 | c.440-416A>G | Intron (SNP) | VAF 11/73 reads (15%) | catalogued as COSV99385109; called by muse, mutect2, varscan2
- IGLV8OR8-1 | n.168G>T | RNA (SNP) | VAF 11/95 reads (12%) | called by muse, mutect2, varscan2
- LPAL2 | n.321C>T | RNA (SNP) | VAF 15/139 reads (11%) | catalogued as rs775276749; called by muse, mutect2, varscan2
- MORF4 | n.516del | RNA (DEL) | VAF 37/209 reads (18%) | called by mutect2, pindel, varscan2
- OSGIN1 | n.1889G>T | RNA (SNP) | VAF 9/52 reads (17%) | catalogued as COSV100534001, COSV100534180; called by muse, mutect2, varscan2
- TUBB7P | n.1287del | RNA (DEL) | VAF 37/192 reads (19%) | called by mutect2, pindel, varscan2
